Somatic mutation profile of tumor specimen TCGA-A7-A56D-01A (aliquot TCGA-A7-A56D-01A-11D-A27P-09) from TCGA case TCGA-A7-A56D, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.3 years (30,783 days).
Specimen TCGA-A7-A56D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ed37d83-ace0-4e69-bd1d-daf5c22f4a2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A56D-10A (Blood Derived Normal), aliquot TCGA-A7-A56D-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/426487cf-8c8d-4a48-97bf-3907b026a3ed

The open-access MAF lists 136 somatic variants for this specimen: 95 protein-altering or splice-affecting, 39 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 39, Nonsense Mutation 10, In Frame Del 2, Frame Shift Del 2, RNA 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HACE1 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs759641985, COSV53504877; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1138_1140del p.L380del (on ENST00000521381 / NM_181523.3; = p.L110del on NM_181504.4) | In Frame Del (DEL) | VAF 26/52 reads (50%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TSC2 | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as rs45517340, CD052530, CM991214, COSV51915136; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.8588C>G p.S2863* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV71291516; called by muse, mutect2, varscan2
- ADAM30 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.206); catalogued as COSV65560571; called by muse, mutect2
- ALG3 | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV99891150; called by muse, mutect2
- ANKLE2 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV61710608; called by muse, mutect2, varscan2
- ANKRD36B | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV51534830; called by muse, mutect2, varscan2
- ANO5 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs377553546, CM155981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP12A | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61837379; called by muse, mutect2, varscan2
- BDH1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV64018306; called by muse, mutect2
- BPIFA1 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV62824905; called by muse, mutect2, varscan2
- CAMK2B | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99323016; called by muse, mutect2
- CEP350 | c.8458G>A p.E2820K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.476); catalogued as rs755417181, COSV62606442; called by muse, mutect2, varscan2
- CHST13 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as rs779854156, COSV100081119; called by muse, mutect2
- CKMT2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs548849398, COSV54172310; called by muse, mutect2, varscan2
- CTBP2 | c.1155C>T p.Y385= | Splice Region (SNP) | VAF 14/74 reads (19%) | catalogued as rs781290075, COSV58335911; called by muse, mutect2, varscan2
- DIAPH1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53881157, COSV53883442; called by muse, mutect2, varscan2
- DNAI4 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV64030438; called by muse, mutect2
- DOP1B | c.6487C>A p.P2163T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67694482; called by muse, mutect2, varscan2
- EFCAB12 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.162); catalogued as rs1259088732, COSV99998882; called by muse, mutect2
- EPHB4 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.213); catalogued as rs146064780, COSV62269741; called by muse, mutect2
- EPYC | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs776991646, COSV53800902; called by muse, mutect2, varscan2
- ERBB3 | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as rs1044978284, COSV57258528; called by muse, mutect2, varscan2
- FHOD1 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV50759919, COSV50764276; called by muse, mutect2, varscan2
- FLG | c.10430G>A p.R3477H | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.02); catalogued as rs201858426, COSV64238229; called by muse, mutect2
- FMR1 | c.1822G>T p.G608C | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); catalogued as COSV54426861; called by muse, mutect2
- GPR141 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57732016, COSV57733226; called by muse, mutect2, varscan2
- GPR141 | c.735G>C p.R245S | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57733238; called by muse, mutect2, varscan2
- GPR141 | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.071); catalogued as COSV57731196, COSV57733250; called by muse, mutect2, varscan2
- HMCN1 | c.6196C>T p.R2066* | Nonsense Mutation (SNP) | VAF 61/136 reads (45%) | catalogued as COSV54919730; called by muse, mutect2, varscan2
- ICE1 | c.4735C>T p.H1579Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as COSV56828847; called by muse, mutect2, varscan2
- IGFN1 | c.3619G>A p.D1207N (on ENST00000295591 / NM_001367841.1; = p.D3664N on NM_001164586.2) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.184); catalogued as COSV55178692, COSV55182361; called by muse, mutect2, varscan2
- IK | c.1113C>G p.D371E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1471666838, COSV70257999; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNH1 | c.2400C>A p.F800L (on ENST00000271751 / NM_172362.3; = p.F773L on NM_002238.4) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV55092039; called by muse, mutect2, varscan2
- KIF13A | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV52452822; called by muse, mutect2, varscan2
- KRTAP4-1 | c.434C>T p.S145F (on ENST00000398472; = p.S126F on NM_033060.3) | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.03); catalogued as COSV66649213; called by muse, mutect2, varscan2
- LAMA2 | c.5483T>C p.I1828T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70352036; called by mutect2, varscan2
- LMTK2 | c.4252G>C p.E1418Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51999845; called by muse, mutect2, varscan2
- MAGEA6 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as rs1445974301, COSV61449220; called by muse, mutect2, varscan2
- MAN1A1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63781646; called by muse, mutect2
- MCCC2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.597); catalogued as COSV100040135; called by muse, mutect2
- MCM10 | c.871G>A p.E291K (on ENST00000484800 / NM_182751.3; = p.E290K on NM_018518.5) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV66335633; called by muse, mutect2, varscan2
- METTL27 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52896601; called by muse, mutect2, varscan2
- MFRP | c.175G>A p.G59S (on ENST00000449574; = p.G435S on NM_031433.4) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV100793436, COSV64128874; called by muse, mutect2, varscan2
- MMP1 | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100187943; called by muse, mutect2
- MUC5B | c.2488C>T p.H830Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1355855405, COSV71594205; called by muse, mutect2, varscan2
- MXRA5 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 35/222 reads (16%) | catalogued as COSV54242823, COSV54247433; called by muse, mutect2, varscan2
- NDC80 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs1183027676, COSV55247222, COSV55247805; called by muse, mutect2, varscan2
- PABPC4 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as COSV104425274, COSV63293546; called by muse, mutect2
- PASK | c.3823G>A p.V1275I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as COSV52156422; called by muse, mutect2, varscan2
- PCYOX1 | c.52T>A p.L18M | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52475820, COSV52477464; called by muse, mutect2, varscan2
- PDE6A | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV54929585; called by muse, mutect2, varscan2
- PLCXD2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs142045095; called by muse, mutect2
- PLEKHH3 | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV52218788; called by muse, mutect2, varscan2
- PNMA8A | c.718C>G p.R240G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV58138102, COSV58139624; called by muse, mutect2, varscan2
- PPFIA2 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100331902, COSV61043239; called by muse, mutect2, varscan2
- PPP1R21 | c.2321C>T p.S774F (on ENST00000294952 / NM_001135629.3; = p.S763F on NM_152994.5) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV54286856; called by muse, mutect2, varscan2
- RALGAPA1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV51889799; called by muse, mutect2, varscan2
- RBBP9 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as rs540214428, COSV61500106; called by muse, mutect2, varscan2
- RBM6 | c.2317G>C p.D773H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); catalogued as COSV99805342; called by mutect2, varscan2
- RGN | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs782503509, COSV60276440; called by muse, mutect2, varscan2
- RYR1 | c.13834T>A p.W4612R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100615643; called by muse, mutect2
- SCML2 | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99318933; called by muse, mutect2
- SLC25A39 | c.512C>G p.A171G (on ENST00000377095 / NM_001143780.3; = p.A163G on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56588369; called by muse, mutect2, varscan2
- SLITRK2 | c.1134G>C p.K378N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100157685, COSV59427240; called by muse, mutect2
- SMURF2 | c.1678A>G p.I560V | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52317589; called by muse, mutect2, varscan2
- SPAG6 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.529); catalogued as COSV100510248; called by muse, mutect2
- SPATA1 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.553); catalogued as COSV55363664; called by muse, mutect2, varscan2
- SPRR2B | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 42/278 reads (15%) | catalogued as COSV58797303; called by muse, mutect2, varscan2
- TARBP1 | c.1716G>T p.W572C | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50193396; called by muse, mutect2, varscan2
- THAP5 | c.955C>G p.Q319E (on ENST00000415914 / NM_001130475.3; = p.Q277E on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.274); catalogued as COSV57951387; called by muse, mutect2, varscan2
- THTPA | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV55338989; called by muse, mutect2, varscan2
- TMEM30A | c.549A>C p.L183F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.405); catalogued as COSV57875983; called by muse, mutect2, varscan2
- TOR1AIP1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as rs750432849, COSV54870719; called by muse, mutect2, varscan2
- TP53 | c.911del p.T304Ifs*41 | Frame Shift Del (DEL) | VAF 30/79 reads (38%) | catalogued as COSV52772403, COSV53265486, COSV53758554; called by mutect2, pindel, varscan2
- TRPM2 | c.2871C>G p.I957M | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100309057, COSV55973231; called by muse, mutect2, varscan2
- URGCP | c.2748C>G p.N916K (on ENST00000453200 / NM_001077663.3; = p.N907K on NM_017920.4) | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV56249965; called by muse, varscan2
- URGCP | c.2625C>G p.I875M (on ENST00000453200 / NM_001077663.3; = p.I866M on NM_017920.4) | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as COSV56249984; called by muse, varscan2
- URGCP | c.2578C>T p.R860W (on ENST00000453200 / NM_001077663.3; = p.R851W on NM_017920.4) | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1350537344, COSV56250003; called by muse, varscan2
- URGCP | c.1449C>G p.I483M (on ENST00000453200 / NM_001077663.3; = p.I474M on NM_017920.4) | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56250021; called by muse, mutect2
- URGCP | c.509C>A p.S170Y (on ENST00000453200 / NM_001077663.3; = p.S161Y on NM_017920.4) | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV56250190; called by muse, mutect2, varscan2
- XPO5 | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54832766; called by muse, mutect2, varscan2
- ZIM3 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as rs565341168, COSV99518067; called by muse, mutect2
- ZNF221 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV52110334, COSV52110351; called by muse, mutect2, varscan2
- ZNF223 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV71571985; called by muse, mutect2, varscan2
- ZNF283 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV61032010; called by muse, mutect2, varscan2
- ZNF527 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1454016682, COSV62232593; called by muse, mutect2, varscan2
- ZNF547 | c.446T>A p.V149D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.403); catalogued as COSV56581337; called by muse, mutect2, varscan2
- CPSF1 | c.1888G>C p.E630Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.173); called by mutect2, varscan2
- JMJD1C | c.5312_5313dup p.G1772Mfs*14 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- RPL15 | c.560_565delinsTCG p.S187_R189delinsFG | In Frame Del (DEL) | VAF 32/62 reads (52%) | called by pindel, varscan2*
- TEX10 | c.1421dup p.N475Kfs*2 | Frame Shift Ins (INS) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- URGCP | c.799C>T p.R267C (on ENST00000453200 / NM_001077663.3; = p.R258C on NM_017920.4) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ARSH | c.538C>T p.L180= | Silent (SNP) | VAF 35/225 reads (16%) | catalogued as COSV66963509; called by muse, mutect2, varscan2
- DDX49 | c.993C>T p.I331= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV55356400; called by muse, mutect2, varscan2
- DYSF | c.5436C>T p.F1812= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV99246814; called by muse, mutect2
- EIF4H | c.12C>T p.F4= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as rs782437953, COSV56082772; called by muse, mutect2, varscan2
- ELOVL7 | c.459C>T p.I153= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV70918338; called by muse, mutect2, varscan2
- EMC2 | c.6G>T p.A2= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV55210446; called by muse, mutect2, varscan2
- EPC2 | c.1743G>A p.E581= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV51546838; called by muse, mutect2, varscan2
- ESRRB | c.435C>T p.C145= | Silent (SNP) | VAF 68/156 reads (44%) | catalogued as rs1064439; called by muse, mutect2, varscan2
- GABRG3 | c.699G>A p.V233= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV61510063, COSV61525071; called by muse, mutect2, varscan2
- GNPTAB | c.40C>T p.L14= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as rs1272948755, COSV54780453; called by muse, mutect2, varscan2
- GPR141 | c.48G>A p.V16= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV57733184; called by muse, mutect2, varscan2
- IGSF10 | c.6726A>G p.T2242= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV56387767; called by muse, mutect2, varscan2
- IGSF9 | c.579C>T p.I193= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as COSV100829620; called by muse, mutect2
- KDM5C | c.3000C>T p.A1000= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as COSV64767019; called by muse, mutect2, varscan2
- KRT83 | c.183C>T p.A61= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs755364196, COSV53342802; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRSAM1 | c.372G>A p.G124= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs1195797789, COSV55941353; called by muse, mutect2, varscan2
- NEBL | c.813A>G p.K271= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV65802480; called by muse, mutect2
- OLFML3 | c.822C>T p.I274= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs200705182, COSV57435680; called by muse, mutect2, varscan2
- OR2M4 | c.249C>T p.F83= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as rs762946009, COSV60708994; called by muse, mutect2, varscan2
- OSBPL3 | c.447G>A p.Q149= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV57659607; called by muse, mutect2, varscan2
- P3H3 | c.1890C>T p.N630= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1200717104, COSV51834979; called by muse, mutect2, varscan2
- PCDHB7 | c.681C>T p.L227= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs1554280016, COSV50805521, COSV50816717; called by muse, mutect2
- PCOLCE2 | c.969C>T p.I323= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV56000656; called by muse, mutect2, varscan2
- PHYH | c.900C>T p.I300= | Silent (SNP) | VAF 13/162 reads (8%) | catalogued as rs757065674, COSV53816064, COSV53818360; called by muse, mutect2
- PITPNM2 | c.369C>T p.P123= | Silent (SNP) | VAF 53/164 reads (32%) | catalogued as rs776857510, COSV54904438; called by muse, mutect2, varscan2
- PRAMEF6 | c.1122G>A p.L374= | Silent (SNP) | VAF 11/76 reads (14%) | called by mutect2, varscan2
- PTPN21 | c.414A>G p.E138= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs758048059, COSV60850186; called by muse, mutect2, varscan2
- RORB | c.366G>A p.Q122= (on ENST00000396204 / NM_001365023.1; = p.Q111= on NM_006914.4) | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100974324, COSV65335569; called by muse, mutect2
- RPS6 | c.129A>G p.E43= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV59548272; called by muse, mutect2, varscan2
- RXRG | c.1029C>T p.V343= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs138979533; called by muse, mutect2, varscan2
- SCN4A | c.3231C>T p.I1077= | Silent (SNP) | VAF 190/387 reads (49%) | catalogued as COSV71127875; called by muse, mutect2, varscan2
- SCN4A | c.3114C>T p.V1038= | Silent (SNP) | VAF 86/187 reads (46%) | catalogued as rs572541145, COSV71127876; called by muse, mutect2, varscan2
- SLAIN2 | c.93G>A p.L31= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV51908600; called by muse, mutect2, varscan2
- SMARCAD1 | c.1990C>T p.L664= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV100758821; called by muse, mutect2
- SMARCD2 | c.1576C>T p.L526= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as COSV56740799; called by muse, mutect2, varscan2
- TRAF4 | c.852G>A p.L284= | Silent (SNP) | VAF 30/202 reads (15%) | catalogued as COSV52219127; called by muse, mutect2, varscan2
- UAP1 | c.747C>G p.V249= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs144426173; called by muse, mutect2, varscan2
- UCP2 | c.615G>A p.L205= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs754066293, COSV60104781; called by muse, mutect2, varscan2
- URGCP | c.1245C>A p.V415= (on ENST00000453200 / NM_001077663.3; = p.V406= on NM_017920.4) | Silent (SNP) | VAF 34/262 reads (13%) | catalogued as COSV56250037; called by muse, varscan2
- CTSL3P | n.220G>A | RNA (SNP) | VAF 70/199 reads (35%) | catalogued as rs756482365; called by muse, mutect2, varscan2
- MIR526A1 | n.57C>T | RNA (SNP) | VAF 17/51 reads (33%) | catalogued as rs375955707; called by muse, mutect2, varscan2
